Somatic mutation profile of tumor specimen TCGA-44-6776-01A (aliquot TCGA-44-6776-01A-11D-1855-08) from TCGA case TCGA-44-6776, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.6 years (22,150 days).
Specimen TCGA-44-6776-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67691429-74f6-40fb-9c68-f408138b1dad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6776-10A (Blood Derived Normal), aliquot TCGA-44-6776-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/663280fe-02ec-4470-b033-3f45b7364c6a

The open-access MAF lists 210 somatic variants for this specimen: 163 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 44, Nonsense Mutation 13, Frame Shift Del 6, Frame Shift Ins 3, 3'UTR 2, Splice Region 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 39/62 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV50643206; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | hotspot (GDC flag); catalogued as rs1131690940, CM991157, COSV58820792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6173T>A p.L2058* (on ENST00000272895 / NM_173076.3; = p.L1740* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as COSV55966532, COSV55974722; called by muse, mutect2, varscan2
- ABR | c.324C>G p.N108K (on ENST00000302538 / NM_021962.5; = p.N71K on NM_001092.5) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV52151545; called by muse, mutect2
- ACSM5 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59374700; called by muse, mutect2, varscan2
- AMPH | c.858del p.A287Hfs*48 | Frame Shift Del (DEL) | VAF 31/110 reads (28%) | catalogued as COSV57753118; called by mutect2, pindel, varscan2
- ARC | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100751749; called by muse, mutect2, varscan2
- ARC | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV100751750; called by muse, mutect2, varscan2
- ARHGEF25 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 12/125 reads (10%) | catalogued as rs1474370014, COSV54086629; called by muse, mutect2
- ASTN1 | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as rs886869912, COSV62505870; called by muse, mutect2, varscan2
- ATP7A | c.3433G>C p.A1145P | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.208); catalogued as COSV58453517; called by muse, mutect2, varscan2
- C5 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV56327312, COSV56331929; called by muse, mutect2, varscan2
- C8B | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202077631, COSV64779540; called by muse, mutect2, varscan2
- CACNA1C | c.1215C>T p.S405= | Splice Region (SNP) | VAF 40/108 reads (37%) | catalogued as rs751480224, COSV100216745; called by muse, mutect2, varscan2
- CACNG5 | c.386T>G p.I129R | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.664); catalogued as COSV50059532; called by muse, mutect2, varscan2
- CCKBR | c.1305G>C p.R435S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV58105311; called by muse, mutect2, varscan2
- CGA | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63644455, COSV63644955; called by muse, varscan2
- CHD6 | c.4724G>T p.W1575L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64694235; called by muse, mutect2, varscan2
- CHEK1 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54025615; called by muse, mutect2, varscan2
- CNTN3 | c.1067C>G p.A356G | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV55183665; called by muse, mutect2, varscan2
- COL11A1 | c.4120C>T p.Q1374* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV62196579; called by muse, mutect2, varscan2
- COL4A1 | c.4030G>T p.G1344C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65431776; called by muse, mutect2, varscan2
- CRISPLD1 | c.1244G>T p.R415I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51549059, COSV51552960; called by muse, mutect2, varscan2
- CWH43 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV56943824; called by muse, mutect2, varscan2
- CYP11B2 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV59997737; called by muse, mutect2, varscan2
- CYP2C9 | c.991A>T p.I331F | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV53252655; called by muse, mutect2, varscan2
- DCTN4 | c.427C>A p.R143= | Splice Region (SNP) | VAF 116/348 reads (33%) | catalogued as COSV69783064; called by muse, varscan2
- DDX54 | c.2072G>A p.S691N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1299754662, COSV58375996; called by muse, mutect2, varscan2
- DDX60 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67099191; called by muse, mutect2, varscan2
- DIO2 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.735); catalogued as COSV101375920; called by muse, mutect2, varscan2
- DLG3 | c.875A>T p.E292V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52086843; called by muse, mutect2, varscan2
- DMD | c.8066G>C p.R2689T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV58950792; called by muse, mutect2, varscan2
- DSG4 | c.1759T>A p.C587S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV57397353; called by muse, mutect2, varscan2
- DTNA | c.924C>A p.S308R | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.968); catalogued as COSV52024606; called by muse, mutect2, varscan2
- DUS2 | c.999G>T p.R333S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV62709850; called by muse, mutect2, varscan2
- DYNC1I1 | c.1138C>G p.R380G | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61456083, COSV61470906; called by muse, mutect2, varscan2
- ENOX1 | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54917594; called by muse, mutect2, varscan2
- EPHB2 | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65866522; called by muse, mutect2, varscan2
- ERICH3 | c.680T>G p.I227S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100446114, COSV58617723; called by muse, mutect2, varscan2
- FAM135B | c.405C>A p.S135R | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV50525233; called by muse, mutect2, varscan2
- FAM47C | c.2842G>T p.G948W | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs782306470, COSV63723870; called by muse, mutect2, varscan2
- FAM71B | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57230891; called by muse, mutect2, varscan2
- FAT1 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs765342648, COSV71675921; called by muse, mutect2, varscan2
- FBXL7 | c.435C>A p.Y145* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV61652909; called by muse, mutect2
- FRAS1 | c.9985G>T p.D3329Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53645560, COSV99348789; called by muse, mutect2, varscan2
- GAPDHS | c.1046C>A p.T349N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1209150722, COSV55881403; called by muse, mutect2, varscan2
- GFRA1 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62604904, COSV62609106; called by muse, mutect2, varscan2
- GPR101 | c.1192G>C p.A398P | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99981533; called by muse, mutect2, varscan2
- GPR26 | c.613C>A p.R205S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV52936549; called by muse, mutect2, varscan2
- GRID1 | c.1891C>A p.R631S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138984541, COSV60013597; called by muse, mutect2
- HEATR1 | c.3942A>G p.I1314M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.08); catalogued as COSV63982948; called by muse, mutect2, varscan2
- HEATR5B | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51858849; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1064C>A p.A355E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1423704227, COSV52378512, COSV99404424; called by muse, mutect2, varscan2
- HTATSF1 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as COSV54481145, COSV99511449; called by muse, mutect2, varscan2
- IBTK | c.651C>A p.C217* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as COSV60393108; called by muse, mutect2, varscan2
- IFNA6 | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 103/420 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101207026; called by muse, mutect2, varscan2
- IFNA6 | c.491G>T p.W164L | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101207027; called by muse, mutect2, varscan2
- IGBP1P2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs755408550; called by muse, mutect2
- IGHV1-69 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 116/589 reads (20%) | catalogued as rs565310590; called by muse, mutect2, varscan2
- JARID2 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59197459; called by muse, mutect2, varscan2
- KCNC1 | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV56398312; called by muse, mutect2, varscan2
- KCNH2 | c.3176A>G p.D1059G | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51226159; called by muse, mutect2, varscan2
- KCNU1 | c.1782G>T p.K594N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV67759675; called by muse, mutect2, varscan2
- KCNV1 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV52088969; called by muse, mutect2, varscan2
- KDR | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV55767054; called by muse, mutect2, varscan2
- KIF4A | c.3357C>A p.N1119K | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV65545735; called by muse, mutect2
- KRTAP11-1 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.959); catalogued as COSV100190742; called by muse, mutect2, varscan2
- LAMB1 | c.2364C>A p.N788K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.258); catalogued as COSV55969952; called by muse, mutect2, varscan2
- LDLRAD3 | c.265T>A p.F89I | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59688241; called by muse, mutect2, varscan2
- LIN7A | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54027860; called by muse, mutect2, varscan2
- LONRF3 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); catalogued as COSV59156713; called by muse, mutect2, varscan2
- LRRC4B | c.1098C>G p.I366M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100975991, COSV65349627; called by muse, mutect2, varscan2
- LRRC58 | c.532A>G p.I178V | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV55231131; called by muse, mutect2, varscan2
- MAP3K4 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62338304; called by muse, mutect2, varscan2
- MARCHF4 | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56102586, COSV56108320; called by muse, mutect2, varscan2
- MCRS1 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 117/444 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV57792809; called by muse, mutect2, varscan2
- MNDA | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV63742060; called by muse, mutect2, varscan2
- MROH2B | c.2834C>A p.T945N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs758593902, COSV101270825; called by muse, mutect2, varscan2
- MROH5 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.891); catalogued as COSV101436063, COSV71300659; called by muse, mutect2, varscan2
- MUC16 | c.348C>A p.N116K | Missense Mutation (SNP) | VAF 78/136 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV67491783; called by muse, mutect2, varscan2
- MYH15 | c.5171G>C p.R1724T | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs891088990, COSV56314356, COSV56319214; called by muse, mutect2, varscan2
- MYO5B | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53214317, COSV53230466; called by muse, mutect2, varscan2
- MYOM2 | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV50768612; called by muse, mutect2, varscan2
- MYOM2 | c.2186T>A p.L729H | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50768730; called by muse, mutect2, varscan2
- NFKBID | c.95C>T p.A32V (on ENST00000396901; = p.A184V on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV61729909; called by muse, mutect2, varscan2
- NLRC4 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61594657; called by muse, mutect2, varscan2
- NLRP13 | c.1361G>T p.S454I | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV61623961; called by muse, mutect2, varscan2
- NPFFR2 | c.924C>A p.C308* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV58154118; called by muse, mutect2, varscan2
- NPM3 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.76); catalogued as COSV63383289; called by muse, mutect2, varscan2
- OR10A2 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV100225119; called by muse, mutect2, varscan2
- OR2T12 | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100527889; called by muse, mutect2, varscan2
- OR52M1 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64172722; called by muse, mutect2, varscan2
- OR6N1 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58650372; called by muse, mutect2, varscan2
- OR8H1 | c.668C>A p.T223N | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV100477250; called by muse, mutect2, varscan2
- OR8I2 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV56170365; called by muse, mutect2, varscan2
- OR8S1 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV59600833; called by muse, mutect2, varscan2
- OTOF | c.1640C>A p.T547K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs200191563, COSV99718323; called by muse, mutect2, varscan2
- OTOGL | c.494A>G p.H165R (on ENST00000547103; = p.H156R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV72005866; called by muse, mutect2, varscan2
- PABPC3 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV55807003, COSV99879723; called by mutect2, varscan2
- PAK5 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs778974166, COSV62037462; called by muse, mutect2, varscan2
- PBRM1 | c.2192T>A p.M731K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56302974; called by muse, mutect2
- PCDHB12 | c.904A>T p.T302S | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV53400815; called by muse, mutect2, varscan2
- PCDHB2 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV99165836; called by muse, mutect2, varscan2
- PIK3R1 | c.1384G>T p.E462* (on ENST00000521381 / NM_181523.3; = p.E192* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV57139083; called by muse, mutect2, varscan2
- PKN2 | c.1475A>G p.Q492R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100281685; called by muse, mutect2, varscan2
- PNMA3 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100937642; called by muse, mutect2, varscan2
- POLR1A | c.1361A>T p.N454I | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55699455; called by muse, mutect2, varscan2
- POLR3D | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120154; called by muse, mutect2, varscan2
- POP1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV62891941; called by muse, mutect2, varscan2
- PRR15 | c.37T>C p.W13R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100153987; called by muse, mutect2, varscan2
- PTPN4 | c.2080A>T p.T694S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV55308526; called by muse, mutect2, varscan2
- RAB9B | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 76/260 reads (29%) | catalogued as COSV54588336; called by muse, mutect2, varscan2
- RAD51AP1 | c.432T>G p.N144K (on ENST00000228843 / NM_001130862.2; = p.N127K on NM_006479.5) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57412124; called by muse, mutect2
- RIMS2 | c.3208G>C p.G1070R (on ENST00000666250 / NM_001348490.2; = p.G878R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV99178184; called by muse, mutect2, varscan2
- RIN1 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.205); catalogued as rs3181770, COSV60928763; called by muse, mutect2, varscan2
- RIPOR2 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.21); catalogued as COSV52428788; called by muse, mutect2, varscan2
- RPRD2 | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV64818076; called by muse, mutect2, varscan2
- RXFP1 | c.2221C>A p.P741T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.024); catalogued as COSV57056387; called by muse, mutect2, varscan2
- S100A7 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | catalogued as COSV64193738; called by muse, mutect2
- SEMA3D | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52404009; called by muse, mutect2, varscan2
- SERPINB4 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61985006, COSV61985942; called by muse, mutect2, varscan2
- SLC25A42 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59381636; called by muse, mutect2, varscan2
- SLC2A9 | c.348A>G p.I116M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.961); catalogued as COSV53328320; called by muse, mutect2, varscan2
- SLC6A8 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53473427; called by muse, mutect2, varscan2
- SLITRK1 | c.1296C>A p.S432R | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV65677485; called by muse, mutect2, varscan2
- SLURP1 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV55816530; called by muse, mutect2, varscan2
- SMG9 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.185); catalogued as rs1225403405, COSV54216303; called by muse, mutect2, varscan2
- SNRPA | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV99698906; called by muse, mutect2, varscan2
- SNTG1 | c.1356T>A p.F452L | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52470834; called by muse, mutect2, varscan2
- SNX10 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.834); catalogued as COSV58402430; called by muse, mutect2, varscan2
- SPIN4 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100633383; called by muse, mutect2, varscan2
- SVEP1 | c.6229C>A p.R2077S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV52843838; called by muse, mutect2, varscan2
- SYT1 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54034876, COSV99696488; called by muse, mutect2, varscan2
- SYT17 | c.1176C>G p.F392L | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as COSV100810806, COSV62546070; called by muse, mutect2, varscan2
- TCEAL5 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV101013160; called by muse, mutect2, varscan2
- TEX13A | c.986C>A p.P329Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV61181345; called by muse, mutect2, varscan2
- TMTC4 | c.571G>T p.A191S (on ENST00000376234 / NM_001350577.2; = p.A210S on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV60893514; called by muse, mutect2, varscan2
- TNFRSF18 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs531486834, COSV100148936; called by muse, mutect2, varscan2
- TOX3 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV99567871; called by muse, mutect2, varscan2
- TTN | c.2797C>A p.P933T (on ENST00000591111; = p.P887T on NM_003319.4) | Missense Mutation (SNP) | VAF 25/116 reads (22%) | PolyPhen probably damaging (0.998); catalogued as COSV60331848; called by muse, mutect2, varscan2
- TUBB8 | c.393G>C p.Q131H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59114544, COSV59117904; called by muse, mutect2, varscan2
- UBASH3B | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV52502179; called by muse, mutect2, varscan2
- VRTN | c.1735G>T p.E579* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as COSV56443497; called by muse, mutect2, varscan2
- XIRP2 | c.8860A>C p.T2954P (on ENST00000628543; = p.T3129P on NM_152381.6) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV54732727; called by muse, mutect2, varscan2
- XPA | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV64305728; called by muse, mutect2, varscan2
- ZMYM3 | c.3146C>A p.S1049Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58740682; called by muse, mutect2, varscan2
- ZNF107 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61331854; called by muse, mutect2, varscan2
- ZNF678 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as rs1476480546, COSV59388049; called by muse, mutect2, varscan2
- ZSWIM3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs762759364, COSV54850057; called by muse, mutect2, varscan2
- BHLHE40 | c.858dup p.T287Hfs*11 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- CFAP74 | c.288del p.K97Rfs*2 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- CTNNA2 | c.830dup p.A278Cfs*4 | Frame Shift Ins (INS) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- FCGBP | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- IGHV7-81 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- KRT6B | c.224del p.G75Afs*71 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by pindel, varscan2
- L1CAM | c.882_884del p.N294del | In Frame Del (DEL) | VAF 98/338 reads (29%) | called by pindel, varscan2
- MGAT4C | c.1190del p.G397Efs*15 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB9 | c.1838G>C p.G613A | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- PIK3R5 | c.557del p.G186Dfs*85 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- SLC17A9 | c.1043del p.L348Pfs*42 | Frame Shift Del (DEL) | VAF 43/171 reads (25%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.2757dup p.Q920Tfs*25 | Frame Shift Ins (INS) | VAF 96/351 reads (27%) | called by mutect2, pindel, varscan2
- ACTR1A | c.450A>T p.T150= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV64024180; called by muse, mutect2
- ADCY4 | c.903C>G p.L301= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1160003755, COSV53477373; called by muse, mutect2, varscan2
- ADD2 | c.1209G>C p.T403= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as rs556635447, COSV52456964, COSV52461726; called by muse, mutect2, varscan2
- ARHGEF5 | c.2598G>T p.R866= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV50218633; called by muse, mutect2
- CEMIP | c.1668G>A p.P556= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs377174220; called by muse, mutect2, varscan2
- CFAP46 | c.7200C>A p.P2400= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54159315; called by muse, mutect2
- CHST8 | c.603C>A p.G201= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV52863000; called by muse, mutect2
- CPLX4 | c.447C>A p.I149= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV55314940; called by muse, mutect2, varscan2
- DENND4A | c.2781A>G p.Q927= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as rs1273068446, COSV71266971; called by muse, mutect2, varscan2
- DIO2 | c.9C>A p.I3= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV101375921; called by muse, mutect2, varscan2
- FER1L6 | c.4248A>T p.P1416= | Silent (SNP) | VAF 58/175 reads (33%) | catalogued as COSV67552715; called by muse, mutect2, varscan2
- FOXS1 | c.21C>T p.P7= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs564111331, COSV54069208; called by muse, mutect2
- GABRQ | c.675T>A p.T225= | Silent (SNP) | VAF 50/173 reads (29%) | catalogued as COSV64783791; called by muse, mutect2, varscan2
- GUCY2F | c.1692G>T p.A564= | Silent (SNP) | VAF 92/272 reads (34%) | catalogued as COSV54302327, COSV54308252; called by muse, mutect2, varscan2
- HDC | c.658C>A p.R220= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV51080705, COSV99075830; called by muse, mutect2, varscan2
- IGHG2 | c.534G>T p.T178= | Silent (SNP) | VAF 90/310 reads (29%) | called by muse, mutect2, varscan2
- IL12RB2 | c.792C>T p.S264= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV52027063; called by muse, mutect2, varscan2
- KIF12 | c.523C>T p.L175= (on ENST00000640217; = p.L37= on NM_138424.1) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV65118155; called by muse, mutect2, varscan2
- KIF4A | c.921T>A p.T307= | Silent (SNP) | VAF 65/237 reads (27%) | catalogued as COSV65545729; called by muse, mutect2, varscan2
- LAP3 | c.747C>T p.L249= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV56901706; called by muse, mutect2, varscan2
- LILRA2 | c.396G>A p.V132= | Silent (SNP) | VAF 51/397 reads (13%) | catalogued as COSV52196515, COSV52197749; called by muse, mutect2, varscan2
- MAP1B | c.1020C>T p.T340= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV57106031; called by muse, mutect2, varscan2
- MOV10L1 | c.675A>T p.A225= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV53178822; called by muse, mutect2, varscan2
- MROH5 | c.357C>A p.S119= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV101436062; called by muse, mutect2, varscan2
- MSH2 | c.144G>A p.E48= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV51884701; called by muse, mutect2, varscan2
- MXRA5 | c.468C>A p.L156= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV54249561; called by muse, mutect2, varscan2
- NRAP | c.4359T>C p.S1453= (on ENST00000359988 / NM_001322945.2; = p.S1418= on NM_006175.4) | Silent (SNP) | VAF 47/189 reads (25%) | catalogued as COSV63493779; called by muse, mutect2, varscan2
- NYNRIN | c.4611G>A p.P1537= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs745461296, COSV101230645; called by muse, mutect2, varscan2
- OR4D5 | c.387C>A p.P129= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as COSV58309367; called by muse, mutect2, varscan2
- PALLD | c.1359G>A p.A453= | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as rs766551069, COSV54989982; called by muse, mutect2, varscan2
- PCDHGA4 | c.1602C>G p.S534= | Silent (SNP) | VAF 57/191 reads (30%) | catalogued as COSV54027126; called by muse, mutect2, varscan2
- POMK | c.318A>G p.A106= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as COSV58857518; called by muse, mutect2, varscan2
- POU6F2 | c.804G>A p.Q268= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs200308619, COSV68882280; called by muse, mutect2, varscan2
- PRKDC | c.6642A>G p.R2214= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV58063030; called by muse, mutect2, varscan2
- RHBDF2 | c.780C>T p.A260= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs1016988897, COSV100489537; called by muse, mutect2, varscan2
- SIAH2 | c.882C>T p.S294= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs770915741, COSV57262260; called by muse, mutect2, varscan2
- SLC28A1 | c.342C>A p.V114= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV54485642; called by muse, mutect2, varscan2
- SRPK3 | c.669G>A p.G223= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV99473291; called by muse, mutect2, varscan2
- TMEM171 | c.465C>T p.P155= | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as COSV99825037; called by muse, mutect2, varscan2
- UGT3A1 | c.894G>T p.V298= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV57103165; called by muse, mutect2, varscan2
- USP38 | c.1138T>C p.L380= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV61027359; called by muse, mutect2, varscan2
- VIT | c.1605G>T p.G535= (on ENST00000389975 / NM_001177969.1; = p.G550= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV64899067; called by muse, mutect2, varscan2
- WWC3 | c.1854C>A p.L618= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV101080850, COSV66507206; called by muse, mutect2, varscan2
- ZNF423 | c.420G>T p.G140= (on ENST00000563137 / NM_001379286.1; = p.G132= on NM_015069.4) | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV52176761, COSV52203784; called by muse, mutect2, varscan2
- DCAF16 | c.*1A>C | 3'UTR (SNP) | VAF 26/106 reads (25%) | catalogued as COSV101200453; called by muse, mutect2, varscan2
- SNORD114-22 | n.21G>T | RNA (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- UVSSA | c.*9426C>T | 3'UTR (SNP) | VAF 112/385 reads (29%) | catalogued as COSV61351391, COSV61351652; called by muse, mutect2, varscan2
